Surgical pathology report (de-identified scan), TCGA case TCGA-WY-A85C, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Johns Hopkins, specimen TCGA-WY-A85C-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] # [REDACTED]

Accessioned

Birthdate: [REDACTED]

(Age

Loc: [REDACTED]

Gender: M

Spec. Taken

[REDACTED]

=====

INTERPRETATION AND DIAGNOSIS:

1,2) BRAIN TUMOR: DIFFUSE ASTROCYTOMA (WHO GRADE II), SEE COMMENT.

COMMENT: Although the cellularity is moderate, as is the degree of cytological atypia, no mitoses are identified and the MIB-1 rate is low.

[REDACTED]

*Electronic signature

Some stains/tests used in arriving at the diagnosis were performed here using reagents that have not been cleared or approved by the US Food and Drug Administration. These were developed and their performance determined by the .

Their use does not require FDA approval.

=====

Clinical History:

LOW GRADE ASTROCYTOMA- GLIOMA

GROSS DESCRIPTION

(Continued on next page.)

ICD-O-3
Astrocytoma, grade II 9400/3
CNS
Brain, supratentorial NOS C71.0
path
Brain NOS C71.9
J 06/10/14

[page 2 of 2]
Patient: [REDACTED]
[REDACTED] # [REDACTED]

Path# [REDACTED]
Page 2

PART #1: FS: BRAIN TUMOR

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS: STAFF PATHOLOGIST: [REDACTED]
OTHER PATHOLOGIST/P.A.: [REDACTED]

Brain tumor: Infiltrating glioma.

Dictated by [REDACTED]

The specimen is received in saline labeled with the patient's name [REDACTED] and designated 'Brain tumor.' It consists of multiple soft pink-red fragments of tissue measuring 4.5 x 1.5 x 0.4 cm in aggregate dimension. Touch preps were performed and the specimen is entirely submitted.

SUMMARY OF SECTIONS

1 - FSC - M
1 - A - M
2 - TOTAL - M

PART #2: BRAIN TUMOR

Resident Pathologist: [REDACTED]

Dictated by [REDACTED]

The specimen is received in saline labeled with the patient's name [REDACTED] and designated 'Brain tumor.' It consists of multiple fragments of pink-tan soft tissue measuring 1 x 0.5 x 0.2 cm in aggregate. The specimen is submitted in its entirety in lens paper.

SUMMARY OF SECTIONS

1 - A - M
1 - TOTAL - M

Other Surgical Pathology Specimens known to the computer: [REDACTED]

(End of Report)

printed

Logistics Discrepancy		✓
PNA Discrepancy		✓
For Malignancy History		✓

Source: NCI Genomic Data Commons file 0772e92f-aefd-41dc-aab1-bdd2b17c7f21 (TCGA-WY-A85C.2CB63EDD-F6C4-4CE9-AB8D-E6A5172E43FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).